Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7480, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7480-01A (Primary Tumor).

[page 1 of 2]
Microscopic

1. Permanent section of the frozen section specimen demonstrates only poorly cellular dense fibrous connective tissue. No neoplasm identified
- 2, 10, 13. Permanent section of the frozen section specimen demonstrates a mildly hypercellular glial neoplasm that diffusely infiltrates the parenchyma which is predominantly white matter. There is edema as well. Atypia is mild to moderate. No mitotic figures are seen. There is no microvascular proliferation or necrosis. No mitotic figures are identified.
- 3,7. Permanent section of the frozen section specimen and unfrozen material again demonstrate a modestly hypercellular glial neoplasm that is more diffusely infiltrative than cellular. The features are otherwise as described in specimen 2. No mitotic figures are identified.
- 4, 8 Permanent section of the frozen section specimen and unfrozen material demonstrate a mildly hypercellular, apparently low grade glioma that diffusely infiltrates the gray and white matter. The features are as previously described, but this specimen is more cellular than either specimen 2 or 3. No mitotic figures are identified.
- 5, 9. permanent section of the frozen section specimen and unfrozen material confirm the presence of a cellular and infiltrating apparently low grade glioma. In addition, a nodular area with numerous foci of dystrophic calcifications are seen. No mitotic figures are identified.
6. Sections demonstrate variably thickened and poorly cellular dense irregular fibrous connective tissue. The tissue demonstrates multifocal reactive changes including edema, macrophage infiltrates, chronic inflammation and microcalcifications. Focally, the fibrous tissue is adherent to gliotic brain parenchyma which also demonstrates old hemorrhage. No neoplasm is seen. No mitotic figures are identified.
11. Permanent section of the frozen section specimen demonstrates a modestly hypercellular glial neoplasm that diffusely infiltrates the white matter. Although qualifying as cellular tumor, this specimen as cellular tumor, this specimen is less cellular than any of the previous specimens.
12. Permanent section of the frozen section specimen demonstrates a modestly hypercellular glial neoplasm that diffusely infiltrates gray and white matter. A large band of dystrophic calcification is also seen. The specimen is less cellular than most of the previous biopsies, but more than specimen 11.

Addendum discussion:

MIB-1 reactivity varies greatly within the tumor. In the less cellular areas only a few MIB-1 reactive cells are present with a labeling index of <1% to about 3%. However, in some of the moderately cellular areas there are patchy areas of high MIB-1 reactivity. In these areas the labeling of 12.5% is calculated. Based on the overall findings, the MIB-1 labeling suggest anaplastic progression in the background of a low grade glioma.

Final Addendum Diagnosis:

1. poorly cellular fibrous tissue (reactive dura/scar), no neoplasm identified.
2. ,10, 13 **anaplastic oligoastrocytoma**
3. ,7 cellular and infiltrating glioma

[page 2 of 2]
- 4. ,8 positive for cellular and infiltrating glioma
- 5. positive for cellular and infiltrating glioma
- 11. positive for infiltrating glioma
- 12. positive for infiltrating glioma

Source: NCI Genomic Data Commons file 927678ef-0cb9-4504-bd17-e1681ba71541 (TCGA-HT-7480.289B59D0-0A44-4D34-A991-B94846E470C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).